Somatic mutation profile of tumor specimen TCGA-EM-A22J-01A (aliquot TCGA-EM-A22J-01A-11D-A17V-08) from TCGA case TCGA-EM-A22J, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 56.2 years (20,539 days).
Specimen TCGA-EM-A22J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 140f813f-587a-48c9-99f9-401c7e3fd7f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22J-10A (Blood Derived Normal), aliquot TCGA-EM-A22J-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23a76f5f-d2e0-4029-a37d-f054d03eb281

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 65/163 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH4 | c.1046A>T p.D349V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55501190; called by muse, mutect2, varscan2
- DIDO1 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV56621253; called by muse, mutect2, varscan2
- ENPP7 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as COSV100093340; called by muse, mutect2, varscan2
- IL16 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57264905; called by muse, mutect2, varscan2
- LDLRAD3 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as rs371720202; called by muse, mutect2, varscan2
- MAU2 | c.286T>C p.S96P | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV53236174; called by muse, mutect2, varscan2
- NLRP4 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs772896166, COSV56716489; called by muse, mutect2, varscan2
- STK25 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57263828; called by muse, mutect2
- BCAT1 | c.981_982dup p.M328Rfs*40 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- IRF2BPL | c.1050_1061delinsA p.N350Kfs*69 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by pindel, varscan2*
- ATP11A | c.1539G>C p.A513= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV52115077; called by muse, mutect2
- CLDN15 | c.18A>G p.E6= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV56191401; called by muse, mutect2
- FBN2 | c.5808T>C p.D1936= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV52522973; called by muse, varscan2
- PCDHB5 | c.1242C>T p.A414= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV50650891; called by muse, mutect2, varscan2
